Gene-level copy-number profile of tumor specimen MP2PRT-PATHCR-TMP1-A from MP2PRT case MP2PRT-PATHCR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,364 days).
Specimen MP2PRT-PATHCR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ac0ecc16-5605-49b9-bf24-fe6b857c1b7d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PATHCR-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,725 have no estimate.
https://portal.gdc.cancer.gov/files/24bc74a1-11e7-428c-8a1f-4cf52b7916cf

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 231; copy number 1: 4,547; copy number 2: 54,020; copy number 3: 100.

Homozygous deletions (total copy number 0; autosomes only): 231 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–89,245,596, 41 genes (within-gene range 0–2): MALLP2, AC244205.1, MIR4436A, IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30.
- chr9:21,802,636–22,128,103, 14 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr14:105,851,705–106,130,072, 63 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,170,749–106,171,052, 1 gene (within-gene range 0–1): IGHVIII-16-1.
- chr14:106,556,936–106,675,544, 25 genes (within-gene range 0–1): IGHV3-49, IGHVII-49-1, IGHV3-50, IGHV5-51, IGHV8-51-1, IGHVII-51-2, IGHV3-52, IGHVII-53-1, IGHV3-54, IGHV4-55, IGHV7-56, IGHV3-57, IGHV1-58, IGHV4-59, IGHV3-60, RNA5SP389, IGHVII-60-1, IGHV4-61, IGHV3-62, IGHVII-62-1, IGHV3-63, IGHV3-64, IGHV3-65, IGHVII-65-1, IGHV3-66.
- chr22:22,032,745–22,162,681, 18 genes (within-gene range 0–2): IGLVI-68, AC245452.4, AC245452.3, IGLV10-67, AC245452.2, IGLVIV-66-1, IGLVV-66, IGLVIV-65, IGLVIV-64, IGLVI-63, IGLV1-62, AC245517.5, IGLV8-61, AC245517.1, ABHD17AP5, AC245517.4, AC245517.3, IGLV4-60.
- chr22:22,395,018–22,896,111, 69 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,691. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
